Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A2OP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A2OP-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Lymph node, right periaortic, excision
- No carcinoma identified in five lymph nodes (0/5)

B: Lymph node, left periaortic, excision
- No carcinoma identified in two lymph nodes (0/2)

C: Lymph node, right pelvic, excision
- No carcinoma identified in nine lymph nodes (0/9)

D: Lymph node, left pelvic, excision
- No carcinoma identified in three lymph nodes (0/3)

E: Uterus, cervix, bilateral ovaries and fallopian tubes,
hysterectomy with bilateral salpingoophorectomy:

Location of tumor: Endometrium

1CD-0-3

Histologic type: Endometrioid

adenocarcinoma, endometrioid, NOS
8380/3

Histologic grade (FIGO): Grade III

Site: endometrium C54.1

fw 8/24/11

Extent of invasion: Tumor invades the superficial myometrium

Myometrial invasion: Inner half

Depth: 2 mm Wall thickness: 2.1 cm Percent: 10%

Serosal involvement: Not identified

Lower uterine segment involvement: Not identified

Cervical involvement: Not identified

Adnexal involvement (see below): Not identified

Other sites: Not applicable

Cervical/vaginal margin and distance: Free of carcinoma

Lymphovascular Space Invasion: Not identified

Regional lymph nodes (see other specimens):

Total number involved: 0

Reviewed In:	fw 8/24/11	8/22/11

[page 2 of 5]
Total number examined: 19

Other Pathologic findings:

- Endometrial polyps, atrophic type
- Leiomyomata

Tumor estrogen receptor and progesterone receptor immunohistochemistry results are pending.

AJCC Pathologic stage: pT1a pN0

FIGO (2008 classification) Stage grouping: IA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right: Stromal hyperthecosis; surface epithelial inclusions

Ovary, left: Stromal hyperthecosis

Fallopian tube, right: Walthard nests

Fallopian tube, left: No diagnostic histopathologic change

Clinical History:

The patient is a -year-old female with endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "right periaortic" and is received in formalin. The specimen consists of two fragments of yellow/tan fibroadipose tissue that measure 4.5 x 1.2 x 0.7 cm. Within fibroadipose tissue, four lymph node candidates are identified that range in size from 0.7 up to 1.5 cm in greatest dimension.

Block Summary:

- A1 - Two lymph node candidates
- A2 - One lymph node candidate
- A3 - One lymph node candidate, NTR

Container B is additionally labeled "left periaortic" and is

[page 3 of 5]
received in formalin. The specimen consists of a single fragment of yellow/tan fibroadipose tissue that measures 1.5 x 1.0 x 0.9 cm. Within fibroadipose tissue two lymph node candidates are identified. These range in size from 0.5 up to 1.3 cm in greatest dimension.

Block Summary:

B1 - One lymph node candidate

B2 - One lymph node candidate, bisected, NTR.

Container C is additionally labeled "right pelvic" and is received in formalin. The specimen consists of a single fragment of yellow/tan fibroadipose tissue that measures 5.0 x 4.5 x 1.2 cm. Fourteen lymph node candidates are identified within fibroadipose tissue and range in size from 0.4 up to 4.5 cm in greatest dimension. The largest lymph node measures 4.5 x 2.3 x 0.7 cm.

Block Summary:

C1 - Six lymph node candidates

C2 - Five lymph node candidates

C3 - One lymph node candidate, bisected

C4 - One lymph node candidate, bisected

C5-C7 - Largest lymph node candidate, sectioned

C8 - Remaining fibroadipose tissue, NTR

Container D is additionally labeled "left pelvic" and is received in formalin. The specimen consist of single fragment of yellow/tan fibroadipose tissue that measures 4.0x 3.5 x 0.8 cm. Three lymph node candidates are identified within the specimen and range in size from 0.7 up to 3 cm in greatest dimension. The largest lymph node candidate measures 3.2 x 2.2 x 0.6 cm.

Block Summary:

D1 - Two lymph node candidates

D2-D3 - Largest lymph node candidate, sectioned

D4 - Remaining fibroadipose tissue, NTR

Specimen E:

Received is one appropriately labeled container, additionally labeled "

Adnexa: Present bilaterally

Weight: 305 grams

Shape: Pear shaped

Dimensions:

[page 4 of 5]
height: 14.0 cm

anterior to posterior width: 7.0 cm

breadth at fundus: 9.0 cm

Serosa: Pink/tan and smooth. Inking is performed with anterior/blue, and posterior/black.

Cervix:

length of endocervical canal: 3.1 cm

ectocervix: Pink/tan, shiny with hyperemia

endocervix: Tan and trabeculated

Endomyometrium:

length of endometrial cavity: 5.2 cm

width of endometrial cavity at fundus: 5.5 cm

tumor findings:

dimensions: 5.0 x 4.0 x 2.0 cm

appearance: White/tan, friable exophytic, polypoid mass with areas of hemorrhage noted centrally.

location and extent: Extending from the left hand side of the fundus with extension down into the posterior corpus.

myometrial invasion: Inner one-half

thickness of myometrial wall at deepest gross invasion: 2.1 cm

other findings or comments: A firm white/tan, whorled nodule is noted submucosally within the myometrium and measures 3 cm in greatest diameter. It is homogeneous throughout without hemorrhage or mixed edematous change noted.

Adnexa:

Right ovary:

dimensions: 3.5 x 1.9 x 0.9 cm

external surface: Pink/tan and vaguely cerebriform

cut surface: White/yellow and vaguely nodular

Right fallopian tube:

dimensions: 5.5 x 0.7 cm

other findings: No

Left ovary:

dimensions: 3.4 x 2.6 x 0.8 cm

external surface: Yellow/tan and vaguely cerebriform

cut surface: Yellow/white and nodular

Left fallopian tube:

dimensions: 5.2 x 0.8 cm

other findings: No

Lymph nodes: Assessed separately

Other comments: No

Digital photograph taken: No

Tissue submitted for special investigations: Yes. Tumor to tissue procurement.

[page 5 of 5]
Block Summary:

E1 - anterior cervix
E2 - anterior lower uterine segment
E3 - anterior corpus
E4 - anterior fundus, right
E5 - anterior fundus, left
E6 - posterior cervix
E7 - posterior lower uterine segment
E8 - posterior corpus, superficial
E9 - posterior corpus, deep
E10 - posterior fundus, superficial
E11 - posterior fundus, deep
E12 - right ovary and fallopian tube
E13 - left ovary and fallopian tube
E14-E15 - cervix and lower uterine segment
E16-E18 - additional sections of endometrial tumor

Procedures/Addenda:

Addendum

Addendum

The following addendum is issued to report the results of estrogen and progesterone receptor and p63 immunohistochemical studies.

Results:

Estrogen receptor (Ventana, clone SP1):

Interpretation: Approximately 60-70% of tumor cells show moderate (2+/3) nuclear immunoreactivity.

Progesterone receptor (Ventana, clone 1E2):

Interpretation: Approximately 5% of tumor cells show moderate (2+/3) nuclear immunoreactivity.

p63: Tumor is negative (with a positive control slide).

Site: Endometrium

Performed on block: E10

Fixation: 10% neutral buffered formalin

Fixation time: Not specified.

Comment:

The lack of p63 staining in the confluent areas of tumor growth supports interpretation as adenocarcinoma with extensive solid pattern growth and supports classification as grade 3 endometrioid adenocarcinoma.

Source: NCI Genomic Data Commons file c640e61b-7c49-4cc1-85f2-8fbfc723f0fa (TCGA-EY-A2OP.E16B08BE-7F2E-4F0E-9FC8-40FCC29F7BC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).